Gene-level copy-number profile of tumor specimen TCGA-JY-A6FA-01A from TCGA case TCGA-JY-A6FA, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 52.0 years (18,978 days).
Specimen TCGA-JY-A6FA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.1dad1b88-4d25-4f89-8d64-7af71ca17fae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JY-A6FA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9f296854-74f4-492d-b86e-5698bc4a863e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 10,502; copy number 2: 38,713; copy number 3: 7,182; copy number 4: 1,567; copy number 5: 1,195; copy number 6: 473; copy number 7: 43; copy number 8: 2; copy number 9: 39; copy number 11: 22; copy number 12: 22; copy number 13: 14; copy number 14: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JY-A6FA-01A-11D-A33D-01): tumor purity 0.78, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,747,277–61,251,459, 8 genes (within-gene range 0–1): FHIT, AC093418.1, AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr3:70,954,708–71,754,229, 8 genes (within-gene range 0–1): FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1.
- chr9:17,134,982–17,503,923, 2 genes (within-gene range 0–1): CNTLN, SAMM50P1.
- chr9:21,967,752–21,995,301, 1 gene: CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr10:122,832,158–122,898,615, 4 genes (within-gene range 0–1): CUZD1, AC073585.1, FAM24B, C10orf88B.
- chr20:20,659,710–20,659,964, 1 gene: EIF4E2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,819 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,510,510–151,853,712, 29 genes, copy number 6: CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5.
- chr1:160,995,211–161,470,523, 38 genes, copy number 5: F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2, AL831711.1.
- chr2:84,031,140–88,415,004, 126 genes, copy number 5–8 (broad region; genes not listed).
- chr2:97,281,356–98,398,601, 29 genes, copy number 6 (within-gene range 4–6): AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1, AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1, CNGA3, AC092675.2.
- chr2:101,551,592–105,894,274, 71 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:121,178,327–123,073,481, 19 genes, copy number 5: AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1, AC062020.1, LINC01826.
- chr3:135,925,891–198,222,513, 1,088 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:54,603,211–66,431,521, 143 genes, copy number 5–6 (broad region; genes not listed).
- chr6:49,077,712–49,713,590, 12 genes, copy number 13: AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2.
- chr6:49,721,931–49,744,437, 2 genes, copy number 13: AL121950.1, CRISP3.
- chr6:71,652,474–71,652,611, 1 gene, copy number 12: RNU4-66P.
- chr6:81,491,439–85,735,921, 57 genes, copy number 7–11: TENT5A, AL122017.1, AL359693.1, RNA5SP210, AL078599.2, SNORA70, AL078599.1, LINC01526, LINC02542, AL360157.1, IBTK, RNU6-130P, AL121977.1, AL121977.2, TPBG, UBE3D, LAP3P1, AL355613.1, DOP1A, PGM3, RWDD2A, ME1, AL391416.1, PRSS35, SNAP91, AL136972.1, AL139232.1, RIPPLY2, CYB5R4, AL034347.1, LINC02857, MRAP2, CEP162, LINC01611, SMARCE1P2, TBX18, TBX18-AS1, AL590143.1, AL035694.1, AL109941.1, AL139806.1, AL122016.1, AL135903.1, KRT18P64, LINC02535, DUTP5, TPT1P6, NT5E, AL589666.2, SNX14, AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B, AL355615.1, SMIM11P1.
- chr6:89,926,528–90,296,908, 1 gene, copy number 12 (within-gene range 3–12): BACH2.
- chr6:90,001,222–92,180,156, 17 genes, copy number 9–14: RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7, AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3.
- chr6:124,644,434–127,213,609, 24 genes, copy number 7–12 (within-gene range 2–12): RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5, AL356534.1, CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, AL035603.1.
- chr6:142,671,980–143,059,682, 6 genes, copy number 6 (within-gene range 2–6): AL355337.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277.
- chr7:153,887,097–154,894,285, 1 gene, copy number 9 (within-gene range 3–9): DPP6.
- chr7:154,092,201–157,282,686, 57 genes, copy number 5–9: AC006019.2, AC024730.1, AC073336.1, PAXIP1-AS2, PAXIP1, AC093726.1, AC093726.2, PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.5, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.3, AC009403.1, RBM33, SHH, AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2.
- chr8:38,263,130–38,601,200, 13 genes, copy number 5: PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1.
- chr9:25,780,032–26,118,408, 3 genes, copy number 5 (within-gene range 3–5): LINC01241, FAM71BP1, AL353753.1.
- chr10:55,247,755–57,513,425, 11 genes, copy number 5: AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC010996.1, AC025039.1, MIR3924, AL731534.1.
- chr13:23,979,700–24,321,031, 2 genes, copy number 5 (within-gene range 3–5): AL359736.1, SPATA13.
- chr13:24,122,065–24,401,029, 9 genes, copy number 5: IPO7P2, MIR2276, SPATA13-AS1, C1QTNF9, C1QTNF9-AS1, AL359736.2, NUS1P3, LINC00566, CYCSP33.
- chr13:24,420,931–24,512,778, 1 gene, copy number 5 (within-gene range 1–5): PARP4.
- chr13:57,991,350–57,991,464, 1 gene, copy number 6: RNA5SP30.
- chr13:108,207,439–110,307,157, 29 genes, copy number 5: LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1.
- chr14:87,996,345–88,326,907, 9 genes, copy number 5: RNU6-835P, GPR65, AL157955.1, LINC01147, LINC01146, AL133279.2, AL133279.3, AL133279.1, KCNK10.
- chr18:65,865,262–68,114,878, 20 genes, copy number 5–6: AC023394.2, AC023394.1, PRPF19P1, CDH19, RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1.

Autosomal genes at a single copy (total copy number 1): 9,325. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
